Somatic mutation profile of tumor specimen MMRF_1722_1_BM_CD138pos (aliquot MMRF_1722_1_BM_CD138pos_T1_KBS5U_L04818) from MMRF case MMRF_1722, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.6 years (26,149 days).
Specimen MMRF_1722_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 160373bd-6ad4-4efc-a259-d1f0b54974f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1722_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1722_1_PB_Whole_C3_KBS5U_L04830; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f40f7492-78f2-4805-8356-78b508be2693

The open-access MAF lists 137 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 44, Missense Mutation 44, Silent 14, Intron 11, 5'UTR 10, RNA 5, 3'Flank 3, Nonsense Mutation 2, Splice Site 2, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 44/102 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PMP22 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28936682, CM000029, CM991060, COSV56601473; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C7 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57473921; called by muse, mutect2, varscan2
- DCAF16 | c.267A>G p.I89M | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.15); catalogued as rs1262752727; called by muse, mutect2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2
- FBXO33 | c.4T>A p.L2M | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as rs971013266; called by muse, mutect2
- GALNT16 | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs762619892, COSV100545815; called by muse, mutect2, varscan2
- IGLV7-43 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs561653605; called by muse, mutect2, varscan2
- IGLV7-43 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs373346774; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 213/463 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs568673177; called by muse, mutect2, varscan2
- LRRK1 | c.5000C>A p.S1667Y | Missense Mutation (SNP) | VAF 86/159 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs760737980; called by muse, mutect2, varscan2
- MFN2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369948853; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH4 | c.4312C>T p.R1438* | Nonsense Mutation (SNP) | VAF 60/136 reads (44%) | catalogued as rs370141150; called by muse, mutect2, varscan2
- RYR3 | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1363829956; called by muse, mutect2, varscan2
- SEMA3G | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1297326681; called by muse, mutect2, varscan2
- SPANXD | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as rs782166949, COSV65152230; called by muse, mutect2, varscan2
- SPATS1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV55824031; called by muse, mutect2, varscan2
- THNSL1 | c.659T>C p.I220T | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100896345; called by muse, mutect2, varscan2
- ZNF550 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 139/268 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780476522, COSV57303427; called by muse, mutect2, varscan2
- ADARB2 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CAMK2D | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC28B | c.48G>C p.Q16H | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.707); called by muse, varscan2
- CD19 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CDH6 | c.1452C>A p.N484K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CHD9 | c.4810A>C p.K1604Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); called by muse, mutect2
- CHRM5 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPS4 | c.359G>A p.W120* | Nonsense Mutation (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- COPS5 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRB2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CTNNA1 | c.448T>G p.L150V | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- DNAH5 | c.1957A>G p.T653A | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2
- FAM169A | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 118/269 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT4 | c.8573C>G p.T2858R | Missense Mutation (SNP) | VAF 171/362 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FSIP2 | c.15696G>A p.M5232I | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GAS2L3 | c.1562T>A p.M521K | Missense Mutation (SNP) | VAF 150/343 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GCN1 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIF3A | c.26+1G>T p.X9_splice | Splice Site (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- IRF1 | c.364+1G>A p.X122_splice | Splice Site (SNP) | VAF 7/154 reads (5%) | called by muse, mutect2
- KRCC1 | c.779G>T p.*260Lext*10 | Nonstop Mutation (SNP) | VAF 41/259 reads (16%) | called by muse, mutect2, varscan2
- LARP6 | c.1270A>T p.S424C | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MYO3B | c.2492G>A p.C831Y | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); called by muse, mutect2
- SHPK | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TAAR1 | c.709A>C p.M237L | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFCP2L1 | c.541C>A p.H181N | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TMEM61 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TRAV13-2 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2
- TTI1 | c.818T>G p.V273G | Missense Mutation (SNP) | VAF 223/474 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, varscan2
- ZNF654 | c.94G>C p.A32P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAN | c.2733C>A p.G911= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as COSV61363760; called by muse, mutect2, varscan2
- B3GAT1 | c.477C>T p.R159= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs1247871633, COSV56998007; called by muse, mutect2, varscan2
- CDH7 | c.639T>A p.T213= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- CHGB | c.945C>T p.N315= | Silent (SNP) | VAF 76/163 reads (47%) | catalogued as rs779863087; called by muse, mutect2, varscan2
- CPAMD8 | c.1395C>T p.H465= (on ENST00000651564; = p.H418= on NM_015692.5) | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs564189038, COSV52231172; called by muse, mutect2, varscan2
- DENND3 | c.2457T>C p.D819= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs749483662; called by muse, mutect2, varscan2
- DOCK4 | c.5634G>A p.V1878= | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as COSV70241899; called by muse, mutect2
- HRNR | c.441T>C p.S147= | Silent (SNP) | VAF 116/222 reads (52%) | called by muse, mutect2, varscan2
- LRRC6 | c.939C>T p.N313= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs771394029, COSV51546851; called by muse, mutect2, varscan2
- MARCO | c.1512C>T p.G504= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2
- MSRA | c.90C>A p.I30= | Silent (SNP) | VAF 30/194 reads (15%) | catalogued as COSV100412627; called by muse, mutect2, varscan2
- SETD1B | c.4443C>T p.P1481= | Silent (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- TAS2R7 | c.786G>A p.E262= | Silent (SNP) | VAF 68/161 reads (42%) | catalogued as COSV99553807; called by muse, mutect2, varscan2
- ZNF283 | c.147T>C p.A49= | Silent (SNP) | VAF 66/151 reads (44%) | called by muse, mutect2, varscan2
- AC079612.1 | n.3373C>A | RNA (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- AC241952.1 | n.2148A>G | RNA (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- ACSS3 | c.*1779T>G | 3'UTR (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
- AP000851.2 | n.108A>C | RNA (SNP) | VAF 76/404 reads (19%) | called by muse, mutect2, varscan2
- ATF4 | c.-788A>G | 5'UTR (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- ATG2A | chr11:64891404 T>C | 3'Flank (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- BEST3 | c.*8A>G | 3'UTR (SNP) | VAF 26/376 reads (7%) | called by muse, mutect2
- BMP7 | c.*1726T>C | 3'UTR (SNP) | VAF 8/71 reads (11%) | catalogued as rs1193232852; called by muse, mutect2
- BRD3 | c.-79C>A | 5'UTR (SNP) | VAF 77/169 reads (46%) | catalogued as rs201651754; called by muse, mutect2, varscan2
- CASP12 | c.-47T>A | 5'UTR (SNP) | VAF 12/122 reads (10%) | catalogued as rs1466117648; called by muse, mutect2
- CCND1 | c.-102G>T | 5'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, varscan2
- CD93 | c.*1977T>C | 3'UTR (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- CDH2 | c.2514+100C>A | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, varscan2
- CHRNA4 | c.*1614C>T | 3'UTR (SNP) | VAF 95/229 reads (41%) | catalogued as rs763926111; called by muse, mutect2, varscan2
- DACH2 | c.1751-210_1751-208del | Intron (DEL) | VAF 18/28 reads (64%) | catalogued as rs1272735319; called by pindel, varscan2
- DCUN1D1 | c.*2246T>A | 3'UTR (SNP) | VAF 104/309 reads (34%) | called by muse, mutect2, varscan2
- DTX1 | c.-445G>T | 5'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- ETFBKMT | c.*2596C>T | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- ETV5 | c.*1096G>A | 3'UTR (SNP) | VAF 12/111 reads (11%) | catalogued as rs1269871125; called by muse, mutect2, varscan2
- FAM13A | c.*1994A>C | 3'UTR (SNP) | VAF 73/208 reads (35%) | called by muse, mutect2, varscan2
- FAM197Y1 | n.9C>G | RNA (SNP) | VAF 10/15 reads (67%) | called by muse, varscan2
- FBXL7 | c.-71G>A | 5'UTR (SNP) | VAF 4/96 reads (4%) | catalogued as COSV101554417; called by muse, mutect2
- FKBP15 | c.*3043A>G | 3'UTR (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- FOLH1B | n.916A>G | RNA (SNP) | VAF 57/147 reads (39%) | called by muse, mutect2, varscan2
- FTH1 | c.-80C>T | 5'UTR (SNP) | VAF 24/46 reads (52%) | catalogued as rs1442058784; called by muse, mutect2, varscan2
- GASK1B | c.910+1474C>G | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- GCSAML | c.*857T>G | 3'UTR (SNP) | VAF 44/195 reads (23%) | called by mutect2, varscan2
- GMPPB | chr3:49717728 G>T | 3'Flank (SNP) | VAF 13/191 reads (7%) | catalogued as rs1475524830; called by muse, mutect2
- H2BC12 | c.*1_*3delinsC | 3'UTR (DEL) | VAF 61/151 reads (40%) | called by pindel, varscan2*
- HCCS | c.*881T>G | 3'UTR (SNP) | VAF 53/59 reads (90%) | called by muse, varscan2
- HCCS | c.*958T>A | 3'UTR (SNP) | VAF 38/42 reads (90%) | called by muse, varscan2
- HCCS | c.*1033T>G | 3'UTR (SNP) | VAF 42/46 reads (91%) | called by muse, varscan2
- HCFC1 | c.*1317C>A | 3'UTR (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- HK2 | c.*1961G>A | 3'UTR (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- KATNBL1 | c.*878A>C | 3'UTR (SNP) | VAF 54/165 reads (33%) | called by muse, mutect2, varscan2
- KCTD20 | c.*1674C>T | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- KMT2A | c.432+682A>T | Intron (SNP) | VAF 56/129 reads (43%) | catalogued as COSV63290684; called by muse, mutect2, varscan2
- LATS2 | c.*962A>G | 3'UTR (SNP) | VAF 39/54 reads (72%) | called by muse, mutect2, varscan2
- LIMD1 | c.*6105A>G | 3'UTR (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- LPAR6 | c.-90T>C | 5'UTR (SNP) | VAF 60/68 reads (88%) | called by muse, mutect2, varscan2
- LRRTM1 | c.*291T>G | 3'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- MANBA | c.1455+10T>G | Intron (SNP) | VAF 74/156 reads (47%) | called by muse, mutect2, varscan2
- MEF2B | c.769+261C>T | Intron (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- MIPOL1 | c.*2681C>G | 3'UTR (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2, varscan2
- MRPS28 | c.213+186C>T | Intron (SNP) | VAF 64/187 reads (34%) | called by muse, mutect2, varscan2
- NEBL | c.*469C>T | 3'UTR (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- NFIA | c.*2030C>A | 3'UTR (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- NRG3 | chr10:82986618 G>A | 3'Flank (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- NUP133 | c.*124del | 3'UTR (DEL) | VAF 40/125 reads (32%) | called by mutect2, pindel*, varscan2
- OCEL1 | c.-20T>C | 5'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- PAH | c.*612G>T | 3'UTR (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- PARP8 | c.*1216A>T | 3'UTR (SNP) | VAF 30/230 reads (13%) | called by muse, mutect2, varscan2
- PHF13 | c.*795G>C | 3'UTR (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2
- PLCXD3 | c.*835C>G | 3'UTR (SNP) | VAF 44/110 reads (40%) | called by muse, mutect2, varscan2
- PRDM7 | c.*418G>C | 3'UTR (SNP) | VAF 16/207 reads (8%) | called by muse, mutect2
- PSMD12 | c.-44G>C | 5'UTR (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- RAB39B | c.*674A>T | 3'UTR (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- RAB6B | c.*3442G>C | 3'UTR (SNP) | VAF 13/112 reads (12%) | catalogued as rs1032253295; called by muse, mutect2, varscan2
- RASGRP1 | c.1721-311G>C | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- RCSD1 | c.*787G>C | 3'UTR (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- SERPINB9 | c.*1150G>A | 3'UTR (SNP) | VAF 28/72 reads (39%) | catalogued as rs1440553743; called by muse, mutect2, varscan2
- SLC22A1 | c.412-39G>A | Intron (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2
- SLC25A43 | c.*1079G>A | 3'UTR (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- SNX13 | c.*402G>A | 3'UTR (SNP) | VAF 9/240 reads (4%) | catalogued as rs1220418739; called by muse, mutect2
- SRSF6 | c.*133G>T | 3'UTR (SNP) | VAF 145/360 reads (40%) | called by muse, mutect2, varscan2
- TMBIM4 | c.*715_*745del | 3'UTR (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel
- TMEM50B | c.*1626_*1629del | 3'UTR (DEL) | VAF 32/92 reads (35%) | catalogued as rs1463309502; called by mutect2, varscan2
- TNRC6A | c.*2078A>C | 3'UTR (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- TPM4 | chr19:16076086 G>A | 5'Flank (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- TPO | c.2748+99G>A | Intron (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- TXNDC5 | c.*211C>T | 3'UTR (SNP) | VAF 54/116 reads (47%) | catalogued as rs1409117255; called by muse, mutect2, varscan2
- WDR20 | c.432+2649C>A | Intron (SNP) | VAF 72/210 reads (34%) | called by muse, mutect2, varscan2
- ZADH2 | c.*5098C>T | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- ZNF813 | c.*1900A>G | 3'UTR (SNP) | VAF 73/184 reads (40%) | catalogued as rs1448707301; called by muse, mutect2, varscan2
